CCDI case PBBKCM — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/88ea011c-deea-4e68-b575-7a7114fe907b

Demographics
Sex at birth: male; Race: black or african american; Ethnicity: hispanic or latino.

Diagnoses (1)
1. Pilocytic astrocytoma: ICD-O-3 morphology code: 9421/1; Tissue or organ of origin: Cerebellum, NOS; Age at diagnosis: 3.3 years (1,191 days).

Biospecimens (3 samples)
- Sample 0DCUKT: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DCUL1: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DCUL5: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
